Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A1QT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A1QT-01A (Primary Tumor).

Cervical

Date of Procurement

Gross Description:

Microscopic Description:

Diagnosis Details:

1C5-0-3

Comments:

Carcinoma, Squamous cell, large cell,
nonkeratinizing 8072/3

Formatted Path Report:

Site: cervix, NOS C53.9 4/8/11 JWS

CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 5 x 4 x 2 cm

Histologic type: Squamous cell carcinoma, large cell, non-keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Stromal invasion up to 3.0 mm

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Laterality:

NA

Source: NCI Genomic Data Commons file 4468cf32-8a1e-4a0c-ab8d-b42e59ff5064 (TCGA-EA-A1QT.87B05129-51AC-401B-AAEC-CAF13E97061E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).